Gene-level copy-number profile of tumor specimen TCGA-CG-5725-01A from TCGA case TCGA-CG-5725, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 72.1 years (26,329 days).
Specimen TCGA-CG-5725-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.e3423677-8563-46a2-bb28-45880517c880.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CG-5725-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/665c337a-adf2-435d-a543-88bffdd305be

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 186; copy number 1: 23,248; copy number 2: 30,268; copy number 3: 5,555; copy number 4: 456; copy number 5: 81; copy number 7: 3; copy number 8: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CG-5725-01A-11D-1599-01): tumor purity 0.91, ploidy 1.77, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 133 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:145,826,285–146,898,218, 10 genes: METAP2P1, AC079248.1, AC079248.2, RNU7-2P, RPL17P12, OTX2P2, PABPC1P2, AC103881.1, LINC01911, AC062032.1.
- chr6:130,697,312–131,283,535, 5 genes (within-gene range 0–1): AL583803.1, SMLR1, EPB41L2, AKAP7, AL137222.1.
- chr6:154,832,697–155,257,723, 1 gene (within-gene range 0–1): TIAM2.
- chr6:155,004,835–155,005,318, 1 gene: AL136228.1.
- chr9:19,895,800–26,644,595, 95 genes (broad region; genes not listed).
- chr16:78,123,243–78,241,989, 3 genes: AC079414.3, AC009044.1, WWOX-AS1.
- chr21:41,464,300–41,954,018, 16 genes: TMPRSS2, AP001610.1, AP001610.3, AP006748.1, PCSEAT, LINC00111, LINC00479, LINC00112, RIPK4, AP001615.1, MIR6814, PRDM15, AP001619.2, AP001619.1, AP001619.3, C2CD2.
- chr22:28,232,756–28,303,850, 2 genes: SNORD42, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 95 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:53,497,341–53,617,171, 3 genes, copy number 7: GCLC, AL033397.2, AL033397.1.
- chr6:54,602,487–54,625,488, 2 genes, copy number 5: RPL10P10, RPSAP44.
- chr12:63,558,913–65,135,273, 52 genes, copy number 5–8: DPY19L2, AC084357.2, AC027667.1, AC084357.3, AC084357.1, RXYLT1, RXYLT1-AS1, PABPC1P4, SRGAP1, RPL36AP41, AC079866.2, AC079866.1, AC020611.1, AC020611.2, AC025576.3, AC025576.2, AC025576.1, C12orf66, RNU6-1009P, AC012158.1, RNU5A-7P, C12orf56, OOEPP2, ATP6V1E1P3, AC135279.1, XPOT, AC135279.2, AC135279.3, TBK1, AC136977.1, RASSF3, AC078962.2, SNORD83, AC078962.4, MIR548C, MIR548Z, AC078962.1, AC078962.3, AC025262.2, AC025262.1, GNS, TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P, APOOP3.
- chr12:66,950,754–68,687,755, 38 genes, copy number 5 (within-gene range 2–5): AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, AC078983.1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42.

Autosomal genes at a single copy (total copy number 1): 20,915. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
